Somatic mutation profile of tumor specimen TCGA-FD-A3N5-01A (aliquot TCGA-FD-A3N5-01A-11D-A21A-08) from TCGA case TCGA-FD-A3N5, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Posterior wall of bladder; AJCC pathologic stage: Stage II; Tumor grade: High Grade; Age at diagnosis: 69.4 years (25,342 days).
Specimen TCGA-FD-A3N5-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 47d09b2e-4520-4dee-80a4-e4f29c13511e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FD-A3N5-10A (Blood Derived Normal), aliquot TCGA-FD-A3N5-10A-01D-A21A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e79e9fcb-2b75-44b1-8ec2-b9683d0d0fc3

The open-access MAF lists 371 somatic variants for this specimen: 256 protein-altering or splice-affecting, 105 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 215, Silent 105, Nonsense Mutation 13, Frame Shift Del 12, Splice Site 9, Intron 8, Frame Shift Ins 3, Splice Region 2, In Frame Del 2, 5'Flank 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ERCC2 | c.713A>G p.N238S | Missense Mutation (SNP) | VAF 16/61 reads (26%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55538701; called by muse, mutect2, varscan2
- RAD51C | c.670T>C p.Y224H | Missense Mutation (SNP) | VAF 11/43 reads (26%) | hotspot (GDC flag); SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as COSV61676742; called by muse, mutect2, varscan2
- TP53 | c.641A>G p.H214R | Missense Mutation (SNP) | VAF 49/64 reads (77%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.936); catalogued as rs1057519992, CM103210, COSV52670202, COSV52732998, COSV52834506, COSV52887765; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCA1 | c.1670G>A p.R557Q | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV66064625, COSV66068696; called by muse, mutect2, varscan2
- ACTC1 | c.632T>C p.V211A | Missense Mutation (SNP) | VAF 13/23 reads (57%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.187); catalogued as COSV51760279; called by muse, mutect2, varscan2
- ADCY10 | c.2905G>A p.G969S | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV63242995; called by muse, mutect2, varscan2
- ADGRA1 | c.170T>A p.L57Q | Missense Mutation (SNP) | VAF 93/140 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV66926574; called by muse, mutect2, varscan2
- ADGRG1 | c.303A>T p.L101F | Missense Mutation (SNP) | VAF 19/88 reads (22%) | SIFT tolerated (0.32); PolyPhen benign (0.007); catalogued as COSV65636190; called by muse, mutect2, varscan2
- AFF3 | c.1051G>A p.A351T | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT tolerated (0.32); PolyPhen benign (0.007); catalogued as rs1056502135, COSV57863652; called by muse, mutect2, varscan2
- AKAP1 | c.2501-1G>T p.X834_splice | Splice Site (SNP) | VAF 38/76 reads (50%) | catalogued as COSV61806428; called by muse, mutect2, varscan2
- AKAP4 | c.1733T>G p.M578R | Missense Mutation (SNP) | VAF 16/26 reads (62%) | SIFT deleterious (0.02); PolyPhen benign (0.239); catalogued as COSV62074967; called by muse, mutect2, varscan2
- ALX1 | c.710C>A p.T237N | Missense Mutation (SNP) | VAF 38/84 reads (45%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.684); catalogued as COSV57493393; called by muse, mutect2, varscan2
- ANKRD28 | c.1988A>C p.N663T | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.374); catalogued as COSV67519375; called by muse, mutect2, varscan2
- ANXA13 | c.182G>T p.G61V | Missense Mutation (SNP) | VAF 33/156 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as COSV51625199; called by muse, mutect2, varscan2
- AP4B1 | c.674A>G p.Y225C | Missense Mutation (SNP) | VAF 27/59 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56726075; called by muse, mutect2, varscan2
- ARAP2 | c.31A>G p.I11V | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.365); catalogued as COSV58289695; called by muse, mutect2, varscan2
- ARFGAP3 | c.797C>G p.S266C | Missense Mutation (SNP) | VAF 21/34 reads (62%) | SIFT deleterious (0.03); PolyPhen benign (0.379); catalogued as COSV54313301; called by muse, mutect2, varscan2
- ARHGAP26 | c.1753C>G p.R585G | Missense Mutation (SNP) | VAF 140/189 reads (74%) | SIFT deleterious (0.05); PolyPhen benign (0.323); catalogued as rs762950382, COSV50835493; called by muse, mutect2, varscan2
- ASPA | c.61C>G p.H21D | Missense Mutation (SNP) | VAF 42/81 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52153564; called by muse, mutect2, varscan2
- ATP8A2 | c.1215C>A p.D405E | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.826); catalogued as COSV54965542; called by muse, mutect2, varscan2
- AXL | c.2597A>G p.Y866C (on ENST00000301178 / NM_021913.5; = p.Y857C on NM_001699.6) | Missense Mutation (SNP) | VAF 69/144 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56571887; called by muse, mutect2, varscan2
- BRI3BP | c.316G>A p.V106I | Missense Mutation (SNP) | VAF 30/159 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.123); catalogued as rs1000192125, COSV58296342; called by muse, mutect2, varscan2
- C7orf25 | c.749T>A p.L250Q | Missense Mutation (SNP) | VAF 21/83 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63273998; called by muse, mutect2, varscan2
- C9orf152 | c.399C>A p.D133E | Missense Mutation (SNP) | VAF 37/188 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV68763017; called by muse, mutect2, varscan2
- CBFB | c.512T>A p.L171Q | Missense Mutation (SNP) | VAF 53/162 reads (33%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.404); catalogued as COSV51999994; called by muse, mutect2, varscan2
- CC2D1B | c.1979G>C p.R660P | Missense Mutation (SNP) | VAF 42/186 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.346); catalogued as rs759148224, COSV52561621, COSV99429900; called by muse, mutect2, varscan2
- CD46 | c.245G>A p.R82Q | Missense Mutation (SNP) | VAF 40/84 reads (48%) | SIFT tolerated (0.76); PolyPhen probably damaging (0.967); catalogued as rs761000846, COSV59734480; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CDC42BPA | c.2826G>A p.K942= | Splice Region (SNP) | VAF 12/36 reads (33%) | catalogued as COSV62016151; called by muse, mutect2, varscan2
- CDH23 | c.9799C>T p.R3267C | Missense Mutation (SNP) | VAF 19/131 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.884); catalogued as rs201727938; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- CDK19 | c.128+1G>A p.X43_splice | Splice Site (SNP) | VAF 53/151 reads (35%) | catalogued as COSV60451638; called by muse, mutect2, varscan2
- CHSY3 | c.2073G>A p.M691I | Missense Mutation (SNP) | VAF 15/22 reads (68%) | SIFT tolerated (0.44); PolyPhen benign (0.03); catalogued as COSV59282493; called by muse, mutect2, varscan2
- CIT | c.488C>A p.A163D | Missense Mutation (SNP) | VAF 77/174 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.191); catalogued as COSV55876464; called by muse, mutect2, varscan2
- CLIC3 | c.80G>C p.R27P | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs372161131, COSV65406723; called by muse, mutect2, varscan2
- CLSTN2 | c.2018C>G p.A673G | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV71723272; called by muse, mutect2, varscan2
- CNKSR3 | c.507+2T>G p.X169_splice | Splice Site (SNP) | VAF 6/38 reads (16%) | catalogued as COSV72161843; called by muse, varscan2
- CNTFR | c.333G>T p.E111D | Missense Mutation (SNP) | VAF 172/498 reads (35%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.685); catalogued as COSV63634377; called by muse, mutect2, varscan2
- COG5 | c.1541C>T p.T514I | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as COSV51758021; called by muse, mutect2, varscan2
- COL4A3 | c.536C>T p.P179L | Missense Mutation (SNP) | VAF 14/23 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67417667; called by muse, mutect2, varscan2
- CPAMD8 | c.4864G>C p.E1622Q (on ENST00000651564; = p.E1575Q on NM_015692.5) | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as COSV71597010; called by muse, mutect2, varscan2
- CR1 | c.241C>G p.P81A | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT tolerated (0.65); PolyPhen benign (0.143); catalogued as COSV65460653; called by muse, mutect2, varscan2
- CR1 | c.242C>A p.P81Q | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT tolerated (0.54); PolyPhen benign (0.236); catalogued as COSV65458887; called by muse, mutect2, varscan2
- CRAMP1 | c.3099C>A p.F1033L | Missense Mutation (SNP) | VAF 20/89 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.255); catalogued as COSV51964408; called by muse, mutect2, varscan2
- CRB1 | c.1753G>C p.D585H | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.721); catalogued as rs1417188996, COSV66332041, COSV66333445; called by muse, mutect2, varscan2
- CREBBP | c.235G>A p.G79S | Missense Mutation (SNP) | VAF 23/94 reads (24%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.072); catalogued as rs752992134, COSV52133480; called by muse, mutect2, varscan2
- CRY2 | c.1012C>T p.P338S | Missense Mutation (SNP) | VAF 52/234 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.675); catalogued as COSV69888867; called by muse, mutect2, varscan2
- CSF2RB | c.26C>A p.S9Y | Missense Mutation (SNP) | VAF 26/34 reads (76%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV53259520; called by muse, mutect2, varscan2
- CUL9 | c.2179A>C p.R727= | Splice Region (SNP) | VAF 45/134 reads (34%) | catalogued as COSV52731727; called by muse, mutect2, varscan2
- CYP3A4 | c.189A>C p.E63D | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.011); catalogued as COSV60503304; called by muse, mutect2, varscan2
- DCDC1 | c.4959A>G p.I1653M (on ENST00000597505 / NM_001367979.1; = p.I760M on NM_020869.3) | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.083); catalogued as COSV58001214; called by muse, mutect2, varscan2
- DCT | c.766G>A p.V256M | Missense Mutation (SNP) | VAF 25/73 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1175691159, COSV65470166; called by muse, mutect2, varscan2
- DDX5 | c.571T>G p.C191G | Missense Mutation (SNP) | VAF 21/75 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV56750434; called by muse, mutect2, varscan2
- DGCR8 | c.623A>G p.N208S | Missense Mutation (SNP) | VAF 55/75 reads (73%) | SIFT tolerated (0.06); PolyPhen benign (0.027); catalogued as rs1413395556, COSV61226364, COSV61227975; called by muse, mutect2, varscan2
- DHX8 | c.2972A>G p.K991R | Missense Mutation (SNP) | VAF 21/37 reads (57%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as COSV52255064; called by muse, mutect2, varscan2
- DMWD | c.636C>A p.D212E | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); catalogued as COSV52180410; called by muse, mutect2, varscan2
- DPYSL2 | c.1399C>T p.R467C | Missense Mutation (SNP) | VAF 22/73 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs773717246, COSV60784532; called by muse, mutect2, varscan2
- E2F8 | c.983T>C p.I328T | Missense Mutation (SNP) | VAF 36/59 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51464975; called by muse, mutect2, varscan2
- EFCAB7 | c.1066T>C p.W356R | Missense Mutation (SNP) | VAF 44/72 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV64315070; called by muse, mutect2, varscan2
- EFS | c.1627A>T p.T543S | Missense Mutation (SNP) | VAF 36/154 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.015); catalogued as COSV52836522; called by muse, mutect2, varscan2
- EPB41 | c.370G>A p.E124K | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.044); catalogued as COSV58041124, COSV58042822; called by muse, varscan2
- EPHA2 | c.2719C>A p.R907S | Missense Mutation (SNP) | VAF 102/182 reads (56%) | SIFT tolerated (0.8); PolyPhen probably damaging (0.97); catalogued as COSV64454066; called by muse, mutect2, varscan2
- EPHB4 | c.859C>G p.P287A | Missense Mutation (SNP) | VAF 207/629 reads (33%) | SIFT tolerated (0.32); PolyPhen benign (0.13); catalogued as COSV62269782; called by muse, mutect2, varscan2
- F2RL1 | c.1048G>C p.D350H | Missense Mutation (SNP) | VAF 154/217 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV56996259; called by muse, mutect2, varscan2
- FASTKD1 | c.2180A>G p.H727R | Missense Mutation (SNP) | VAF 33/72 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.828); catalogued as COSV71624553; called by muse, mutect2, varscan2
- FAT2 | c.1226A>T p.N409I | Missense Mutation (SNP) | VAF 33/43 reads (77%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as COSV55825224; called by muse, mutect2, varscan2
- FBLN2 | c.1925G>T p.R642L | Missense Mutation (SNP) | VAF 22/81 reads (27%) | SIFT tolerated (0.68); PolyPhen benign (0.021); catalogued as COSV55488340; called by muse, mutect2, varscan2
- FBXL6 | c.1306C>A p.Q436K | Missense Mutation (SNP) | VAF 68/185 reads (37%) | SIFT tolerated (0.76); PolyPhen benign (0.187); catalogued as COSV57352728; called by muse, mutect2, varscan2
- FBXO11 | c.853G>A p.D285N (on ENST00000403359 / NM_001190274.2; = p.D201N on NM_025133.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.39); PolyPhen benign (0.017); catalogued as COSV57023616; called by muse, mutect2, varscan2
- FLG2 | c.2257G>A p.G753R | Missense Mutation (SNP) | VAF 168/456 reads (37%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.953); catalogued as COSV66170989; called by muse, mutect2, varscan2
- FNDC3B | c.2332A>T p.T778S | Missense Mutation (SNP) | VAF 22/111 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.026); catalogued as COSV61046324; called by muse, mutect2, varscan2
- FNIP1 | c.2069A>G p.D690G | Missense Mutation (SNP) | VAF 96/141 reads (68%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.053); catalogued as COSV57198569; called by muse, mutect2, varscan2
- FNIP2 | c.1982G>T p.G661V | Missense Mutation (SNP) | VAF 15/29 reads (52%) | SIFT tolerated (0.05); PolyPhen benign (0.234); catalogued as COSV52443107, COSV52446522; called by muse, mutect2, varscan2
- FOXRED2 | c.334A>G p.R112G | Missense Mutation (SNP) | VAF 114/183 reads (62%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as COSV53400992; called by muse, mutect2, varscan2
- FPGT-TNNI3K | c.1921G>A p.A641T | Missense Mutation (SNP) | VAF 32/101 reads (32%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.919); catalogued as COSV58560558; called by muse, mutect2, varscan2
- FRYL | c.2761A>G p.I921V | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV51954638; called by muse, mutect2, varscan2
- FUT8 | c.58A>C p.T20P | Missense Mutation (SNP) | VAF 88/153 reads (58%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.986); catalogued as COSV61288192; called by muse, mutect2, varscan2
- GON4L | c.622C>G p.Q208E | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.034); catalogued as COSV55198610; called by muse, mutect2, varscan2
- GPR75 | c.1504C>A p.P502T | Missense Mutation (SNP) | VAF 31/141 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV61830061; called by muse, mutect2, varscan2
- GRAMD1C | c.28G>A p.V10M | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.146); catalogued as rs562411629, COSV100822826, COSV63983478; called by muse, mutect2, varscan2
- GREB1 | c.3610C>T p.L1204F | Missense Mutation (SNP) | VAF 22/45 reads (49%) | SIFT tolerated (0.2); PolyPhen benign (0.157); catalogued as rs71446422, COSV52192192; called by muse, mutect2, varscan2
- GRIN1 | c.1084G>T p.V362L | Missense Mutation (SNP) | VAF 28/116 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as COSV59298866; called by muse, varscan2
- GRIN3A | c.647T>C p.L216P | Missense Mutation (SNP) | VAF 47/183 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.983); catalogued as COSV62456359; called by muse, mutect2, varscan2
- GRSF1 | c.1079A>G p.H360R | Missense Mutation (SNP) | VAF 21/83 reads (25%) | SIFT tolerated (0.39); PolyPhen benign (0.084); catalogued as rs752414097, COSV54656444; called by muse, mutect2, varscan2
- GSAP | c.619G>A p.E207K | Missense Mutation (SNP) | VAF 20/134 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.28); catalogued as rs1330458886, COSV57531711; called by muse, varscan2
- GUSB | c.1289T>G p.M430R | Missense Mutation (SNP) | VAF 143/360 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59222757; called by muse, mutect2, varscan2
- HECW1 | c.631+1G>C p.X211_splice | Splice Site (SNP) | VAF 11/50 reads (22%) | catalogued as COSV67835746; called by muse, mutect2, varscan2
- HGFAC | c.1495+1G>A p.X499_splice | Splice Site (SNP) | VAF 275/680 reads (40%) | catalogued as rs754020701, COSV66977139; called by muse, mutect2, varscan2
- HSPA8 | c.1445C>T p.A482V | Missense Mutation (SNP) | VAF 31/70 reads (44%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.048); catalogued as COSV57085020; called by muse, mutect2, varscan2
- IL18RAP | c.1768A>G p.T590A | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT tolerated (0.81); PolyPhen benign (0.006); catalogued as COSV51827715; called by muse, mutect2, varscan2
- IL27 | c.7_8insG p.Q3Rfs*87 | Frame Shift Ins (INS) | VAF 32/134 reads (24%) | catalogued as COSV63559984; called by mutect2, pindel*, varscan2
- INSL4 | c.5C>T p.A2V | Missense Mutation (SNP) | VAF 37/76 reads (49%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV53329608; called by muse, mutect2, varscan2
- IPO5 | c.458A>G p.H153R | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT tolerated (0.65); PolyPhen benign (0.028); catalogued as rs765290143, COSV55157164; called by muse, mutect2, varscan2
- ITGA2B | c.2183C>A p.A728D | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.88); catalogued as COSV52233784, COSV52235040; called by muse, mutect2, varscan2
- ITGA2B | c.2182G>T p.A728S | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.753); catalogued as COSV52233793; called by muse, mutect2, varscan2
- ITGB5 | c.797G>A p.R266Q | Missense Mutation (SNP) | VAF 36/224 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs867662692, COSV56151119; called by muse, mutect2, varscan2
- JUNB | c.423A>C p.K141N | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56878432; called by muse, mutect2, varscan2
- JUNB | c.980A>G p.K327R | Missense Mutation (SNP) | VAF 26/55 reads (47%) | SIFT tolerated (0.07); PolyPhen benign (0.226); catalogued as COSV56878434; called by muse, mutect2, varscan2
- KCNC2 | c.151G>A p.G51S | Missense Mutation (SNP) | VAF 42/66 reads (64%) | SIFT tolerated (0.77); PolyPhen benign (0.042); catalogued as COSV54374431; called by mutect2, varscan2
- KCTD2 | c.161C>T p.P54L | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as rs1449690905; called by muse, mutect2, varscan2
- KCTD8 | c.1075A>G p.S359G | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT tolerated (0.23); PolyPhen benign (0.428); catalogued as COSV63592838; called by muse, mutect2, varscan2
- KEL | c.1048G>T p.V350L | Missense Mutation (SNP) | VAF 124/362 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV62336574; called by muse, mutect2, varscan2
- KIF21A | c.418C>A p.P140T | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.744); catalogued as COSV62766740, COSV62775119; called by muse, mutect2, varscan2
- KL | c.1272G>C p.K424N | Missense Mutation (SNP) | VAF 25/47 reads (53%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.776); catalogued as COSV66308782, COSV66309450; called by muse, mutect2, varscan2
- KLHL30 | c.1145T>C p.I382T | Missense Mutation (SNP) | VAF 31/40 reads (78%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.825); catalogued as COSV59977388; called by muse, mutect2, varscan2
- KRT16 | c.1141A>G p.S381G | Missense Mutation (SNP) | VAF 70/229 reads (31%) | SIFT tolerated (0.16); PolyPhen benign (0.107); catalogued as COSV56968959; called by muse, mutect2, varscan2
- LPO | c.733C>G p.Q245E | Missense Mutation (SNP) | VAF 45/74 reads (61%) | SIFT tolerated (0.06); PolyPhen benign (0.329); catalogued as COSV51860867, COSV99228868; called by muse, mutect2, varscan2
- LRATD1 | c.701C>T p.A234V | Missense Mutation (SNP) | VAF 13/21 reads (62%) | SIFT tolerated (0.09); PolyPhen benign (0.026); catalogued as rs1016426961; called by muse, mutect2, varscan2
- LRP1 | c.4688G>T p.C1563F | Missense Mutation (SNP) | VAF 115/272 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV54519277; called by muse, mutect2, varscan2
- LYZ | c.398G>A p.R133H | Missense Mutation (SNP) | VAF 32/85 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs570121782, COSV54261086; called by muse, mutect2, varscan2
- MAP3K21 | c.1834C>A p.P612T | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.05); catalogued as rs947905288, COSV64042195; called by muse, mutect2
- MAPRE2 | c.5C>T p.P2L | Missense Mutation (SNP) | VAF 92/191 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); catalogued as COSV55817566, COSV55818342; called by muse, mutect2, varscan2
- MAST2 | c.3077C>A p.A1026D | Missense Mutation (SNP) | VAF 36/150 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.969); catalogued as COSV63620146; called by muse, mutect2, varscan2
- MAST2 | c.4974G>C p.W1658C | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.667); catalogued as COSV53109622; called by muse, mutect2, varscan2
- MBD6 | c.1138G>C p.G380R | Missense Mutation (SNP) | VAF 88/183 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.085); catalogued as COSV63075669; called by muse, mutect2, varscan2
- MCM3AP | c.1451C>T p.A484V | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV52442984; called by muse, mutect2, varscan2
- MCMDC2 | c.1229T>C p.I410T | Missense Mutation (SNP) | VAF 21/36 reads (58%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV58038706; called by muse, mutect2, varscan2
- MDC1 | c.4406C>A p.P1469H | Missense Mutation (SNP) | VAF 95/214 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.11); catalogued as COSV64525937; called by muse, mutect2, varscan2
- MDN1 | c.16693T>C p.Y5565H | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.038); catalogued as COSV65525885; called by muse, mutect2, varscan2
- MEGF9 | c.664G>A p.G222R | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64236750; called by muse, mutect2, varscan2
- MOS | c.901G>A p.A301T | Missense Mutation (SNP) | VAF 36/117 reads (31%) | SIFT tolerated (0.41); PolyPhen benign (0.049); catalogued as COSV61336706; called by muse, mutect2, varscan2
- MROH2B | c.1786C>G p.Q596E | Missense Mutation (SNP) | VAF 143/266 reads (54%) | SIFT tolerated (0.18); PolyPhen benign (0.009); catalogued as COSV68186889, COSV68187073; called by muse, mutect2, varscan2
- MTHFS | c.570G>T p.M190I | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT tolerated (0.46); PolyPhen benign (0.003); catalogued as COSV51914854; called by muse, mutect2, varscan2
- MYH11 | c.4117C>G p.L1373V | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.168); catalogued as COSV55562204; called by muse, mutect2, varscan2
- MYH14 | c.1057C>T p.R353W | Missense Mutation (SNP) | VAF 20/93 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs1180983594, COSV51825333; called by muse, mutect2, varscan2
- MYO1B | c.346+1G>T p.X116_splice | Splice Site (SNP) | VAF 20/46 reads (43%) | catalogued as COSV58435033; called by muse, mutect2, varscan2
- NASP | c.751C>A p.Q251K | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.01); catalogued as COSV63113934; called by muse, mutect2
- NIBAN2 | c.645G>A p.M215I | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.037); catalogued as COSV64825009; called by muse, mutect2, varscan2
- NIM1K | c.509A>T p.E170V | Missense Mutation (SNP) | VAF 37/131 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV58143866; called by muse, mutect2, varscan2
- NOTCH4 | c.3623C>A p.P1208Q | Missense Mutation (SNP) | VAF 85/223 reads (38%) | SIFT tolerated (0.22); PolyPhen benign (0.076); catalogued as COSV66682561; called by muse, mutect2, varscan2
- NPHP3 | c.2765A>T p.Y922F | Missense Mutation (SNP) | VAF 44/78 reads (56%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.991); catalogued as COSV58631974; called by muse, mutect2, varscan2
- OCIAD1 | c.593C>G p.T198R | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.975); catalogued as COSV51901761; called by muse, mutect2, varscan2
- ODAM | c.677A>G p.Q226R | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.058); catalogued as COSV68573210; called by muse, mutect2, varscan2
- OR10Z1 | c.647T>C p.I216T | Missense Mutation (SNP) | VAF 33/72 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as COSV63525771; called by muse, mutect2, varscan2
- OR4A16 | c.618G>A p.M206I | Missense Mutation (SNP) | VAF 14/113 reads (12%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0.014); catalogued as COSV59043981, COSV59044318; called by muse, mutect2, varscan2
- OR4M1 | c.579C>G p.F193L | Missense Mutation (SNP) | VAF 32/156 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.083); catalogued as rs777577411, COSV60062643, COSV60063253; called by muse, mutect2, varscan2
- OR52N5 | c.128A>T p.Y43F | Missense Mutation (SNP) | VAF 54/98 reads (55%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.916); catalogued as COSV57699201; called by muse, mutect2, varscan2
- P3H2 | c.1658A>G p.Y553C | Missense Mutation (SNP) | VAF 38/63 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs1040473465, COSV60022715; called by muse, mutect2, varscan2
- PCDH18 | c.592C>T p.L198F | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs771875299, COSV61270468; called by muse, mutect2, varscan2
- PDPN | c.92A>T p.D31V (on ENST00000621990; = p.D107V on NM_006474.4) | Missense Mutation (SNP) | VAF 40/102 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.321); catalogued as COSV53849423; called by muse, mutect2, varscan2
- PDZD2 | c.1552T>C p.Y518H | Missense Mutation (SNP) | VAF 59/110 reads (54%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.942); catalogued as COSV56866039; called by muse, mutect2, varscan2
- PDZD2 | c.5821G>T p.E1941* | Nonsense Mutation (SNP) | VAF 105/203 reads (52%) | catalogued as COSV56872744; called by muse, mutect2, varscan2
- PDZD8 | c.2199T>A p.S733R | Missense Mutation (SNP) | VAF 14/20 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57827251; called by muse, mutect2, varscan2
- PIK3C3 | c.2287G>A p.G763R | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV56282168; called by muse, mutect2, varscan2
- PJA2 | c.1826G>C p.S609T | Missense Mutation (SNP) | VAF 34/63 reads (54%) | SIFT tolerated (1); PolyPhen benign (0.138); catalogued as rs1219209866, COSV63273897; called by muse, mutect2, varscan2
- PKD1L1 | c.4928T>C p.V1643A | Missense Mutation (SNP) | VAF 35/129 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.219); catalogued as COSV56972166; called by muse, mutect2, varscan2
- PLA2R1 | c.1436T>C p.V479A | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.999); catalogued as COSV51783063; called by muse, mutect2, varscan2
- PLAAT5 | c.667A>G p.I223V | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs751385656, COSV57137787; called by muse, mutect2, varscan2
- PLCB1 | c.3578T>G p.V1193G | Missense Mutation (SNP) | VAF 70/154 reads (45%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.007); catalogued as COSV62060273; called by muse, mutect2, varscan2
- PLXNA4 | c.4775G>C p.G1592A | Missense Mutation (SNP) | VAF 13/112 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.453); catalogued as COSV58109385, COSV58145699; called by muse, mutect2, varscan2
- PODN | c.736C>G p.L246V (on ENST00000395871; = p.L198V on NM_153703.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 75/317 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.919); catalogued as COSV57015500; called by muse, mutect2, varscan2
- POLR1C | c.619G>A p.E207K | Missense Mutation (SNP) | VAF 28/153 reads (18%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.991); catalogued as COSV104373663, COSV54829335, COSV54832891; called by muse, mutect2, varscan2
- PPCDC | c.250G>A p.D84N | Missense Mutation (SNP) | VAF 51/96 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61625498; called by muse, mutect2, varscan2
- PPP1R36 | c.260C>T p.A87V | Missense Mutation (SNP) | VAF 114/204 reads (56%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.572); catalogued as COSV53903210; called by muse, mutect2
- PPP1R3A | c.2017A>C p.T673P | Missense Mutation (SNP) | VAF 50/111 reads (45%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.543); catalogued as COSV52887951; called by muse, mutect2, varscan2
- PPP2R5B | c.54dup p.L19Afs*71 | Frame Shift Ins (INS) | VAF 11/78 reads (14%) | catalogued as COSV99376252; called by mutect2, pindel, varscan2
- PRKDC | c.2951A>G p.Y984C | Missense Mutation (SNP) | VAF 23/50 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.789); catalogued as rs1426954599, COSV58058801; called by muse, mutect2, varscan2
- PRR12 | c.2356C>A p.Q786K (on ENST00000615927; = p.Q1607K on NM_020719.3) | Missense Mutation (SNP) | VAF 13/17 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV69818811; called by muse, mutect2, varscan2
- PSMD12 | c.1181C>T p.S394L | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.734); catalogued as COSV62066374; called by muse, mutect2, varscan2
- PTPRN | c.874A>G p.R292G | Missense Mutation (SNP) | VAF 40/56 reads (71%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV55350397; called by muse, mutect2, varscan2
- R3HDM1 | c.1918C>T p.P640S | Missense Mutation (SNP) | VAF 37/74 reads (50%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as COSV51528900; called by muse, mutect2, varscan2
- RANBP2 | c.3502G>T p.D1168Y | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51705113; called by mutect2, varscan2
- RB1 | c.2530A>T p.K844* | Nonsense Mutation (SNP) | VAF 6/11 reads (55%) | catalogued as CM127816, COSV99923528; called by muse, mutect2, varscan2
- RBM5 | c.968C>T p.S323L | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.009); catalogued as rs1438230065, COSV61738401; called by muse, mutect2, varscan2
- REN | c.1213G>A p.A405T | Missense Mutation (SNP) | VAF 25/109 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65818111; called by muse, mutect2, varscan2
- RHBDD2 | c.674_676del p.R225del | In Frame Del (DEL) | VAF 62/213 reads (29%) | catalogued as rs782738083; called by pindel, varscan2
- RIMS2 | c.4712C>T p.P1571L (on ENST00000666250 / NM_001348490.2; = p.P1142L on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51702955; called by muse, mutect2
- RIPPLY3 | c.331T>G p.F111V | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61566950; called by muse, mutect2, varscan2
- RNF181 | c.168G>T p.K56N | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV57818278; called by muse, mutect2, varscan2
- RNFT1 | c.114G>A p.M38I | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV59870177; called by muse, mutect2, varscan2
- RPGRIP1L | c.1120C>G p.H374D | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.021); catalogued as COSV50911685; called by muse, mutect2, varscan2
- RPS7 | c.122G>A p.R41K | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated (0.32); PolyPhen benign (0.077); catalogued as COSV59233210; called by muse, mutect2, varscan2
- RRP8 | c.1298G>A p.G433E | Missense Mutation (SNP) | VAF 28/52 reads (54%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.694); catalogued as COSV54450307; called by muse, mutect2, varscan2
- S1PR5 | c.485C>T p.S162L | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.184); catalogued as COSV61013292; called by muse, mutect2, varscan2
- SASH1 | c.2702C>A p.S901Y | Missense Mutation (SNP) | VAF 35/151 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.259); catalogued as COSV66563754; called by muse, mutect2, varscan2
- SCN2A | c.4017T>G p.N1339K | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV51849270; called by muse, mutect2, varscan2
- SCN4A | c.4010G>A p.R1337Q | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs779953580, CM1410689, COSV71125918; ClinVar: uncertain significance; called by muse, mutect2
- SCN9A | c.5080A>G p.I1694V (on ENST00000303354; = p.I1683V on NM_002977.3) | Missense Mutation (SNP) | VAF 40/160 reads (25%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.982); catalogued as COSV57617678; called by muse, mutect2, varscan2
- SCNN1A | c.775A>G p.I259V | Missense Mutation (SNP) | VAF 32/131 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.723); catalogued as COSV57436639; called by muse, mutect2, varscan2
- SLC39A10 | c.1978G>A p.D660N | Missense Mutation (SNP) | VAF 16/94 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.739); catalogued as rs186318919, COSV62766595, COSV62768422; called by muse, mutect2, varscan2
- SLFNL1 | c.52G>A p.E18K | Missense Mutation (SNP) | VAF 77/152 reads (51%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.039); catalogued as COSV57235128; called by muse, mutect2, varscan2
- SSTR1 | c.1087T>C p.Y363H | Missense Mutation (SNP) | VAF 136/209 reads (65%) | SIFT tolerated (0.53); PolyPhen benign (0.154); catalogued as COSV57456907; called by muse, mutect2, varscan2
- STK4 | c.180A>T p.Q60H | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.93); catalogued as COSV65671279; called by muse, mutect2, varscan2
- STON1 | c.1465A>G p.K489E | Missense Mutation (SNP) | VAF 17/30 reads (57%) | SIFT tolerated (0.17); PolyPhen benign (0.119); catalogued as COSV59134534; called by muse, mutect2, varscan2
- STRN4 | c.1769A>G p.H590R | Missense Mutation (SNP) | VAF 31/106 reads (29%) | SIFT tolerated (0.34); PolyPhen benign (0.253); catalogued as COSV54419919; called by muse, mutect2, varscan2
- STX12 | c.59G>C p.R20P | Missense Mutation (SNP) | VAF 43/86 reads (50%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.764); catalogued as COSV64249680; called by muse, mutect2, varscan2
- SV2B | c.298G>T p.D100Y | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.612); catalogued as COSV57700959; called by muse, mutect2, varscan2
- SYK | c.867A>G p.I289M | Missense Mutation (SNP) | VAF 41/89 reads (46%) | SIFT tolerated (0.09); PolyPhen benign (0.006); catalogued as COSV65329024; called by muse, mutect2, varscan2
- SYNE2 | c.145A>G p.T49A | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as COSV58361868; called by muse, mutect2, varscan2
- TAF8 | c.139G>C p.E47Q | Missense Mutation (SNP) | VAF 24/106 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.871); catalogued as COSV65896633; called by muse, mutect2, varscan2
- TAF9B | c.724_735del p.H242_D245del | In Frame Del (DEL) | VAF 19/32 reads (59%) | catalogued as COSV59371926; called by mutect2, pindel, varscan2
- TFF1 | c.49A>G p.M17V | Missense Mutation (SNP) | VAF 25/80 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52298896; called by muse, mutect2, varscan2
- TMBIM4 | c.607C>T p.H203Y | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.542); catalogued as COSV53969806; called by muse, mutect2, varscan2
- TMEM53 | c.742G>A p.V248M | Missense Mutation (SNP) | VAF 134/295 reads (45%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.931); catalogued as rs769914658, COSV59190713; called by muse, mutect2, varscan2
- TNFRSF1B | c.422G>A p.R141H | Missense Mutation (SNP) | VAF 88/166 reads (53%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.559); catalogued as rs754560287, COSV66164754; called by muse, mutect2, varscan2
- TOP2A | c.2863A>G p.T955A | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0.11); catalogued as rs375158687; called by muse, mutect2, varscan2
- TOP2A | c.2089G>T p.D697Y | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV70733260; called by muse, mutect2, varscan2
- TRIM31 | c.1042G>A p.G348R | Missense Mutation (SNP) | VAF 53/216 reads (25%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV65060001; called by muse, mutect2, varscan2
- TSHZ3 | c.1048G>A p.D350N | Missense Mutation (SNP) | VAF 42/184 reads (23%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.761); catalogued as rs760787125, COSV53668374; called by muse, mutect2, varscan2
- UBN2 | c.3993C>A p.H1331Q | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.038); catalogued as COSV56033463; called by muse, mutect2, varscan2
- UNC5C | c.452G>A p.G151D | Missense Mutation (SNP) | VAF 13/88 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs748735330, COSV71661231; called by muse, mutect2, varscan2
- UQCRH | c.8T>C p.L3P | Missense Mutation (SNP) | VAF 26/98 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.543); catalogued as COSV58441189; called by muse, mutect2, varscan2
- VPS4A | c.380A>G p.N127S | Missense Mutation (SNP) | VAF 85/379 reads (22%) | SIFT tolerated (0.86); PolyPhen benign (0); catalogued as COSV54751340; called by muse, mutect2, varscan2
- WASF2 | c.142G>A p.E48K | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV71006224; called by muse, mutect2, varscan2
- WDFY3 | c.1985A>G p.E662G | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.829); catalogued as COSV55708771; called by muse, mutect2, varscan2
- WNK1 | c.2752G>T p.A918S | Missense Mutation (SNP) | VAF 48/96 reads (50%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as COSV60040003; called by muse, mutect2, varscan2
- WNK2 | c.4259C>G p.P1420R (on ENST00000297954 / NM_001282394.1; = p.P1383R on NM_006648.3) | Missense Mutation (SNP) | VAF 22/38 reads (58%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV52951494; called by muse, mutect2, varscan2
- ZBTB7A | c.1685G>A p.G562D | Missense Mutation (SNP) | VAF 22/119 reads (18%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.006); catalogued as COSV59328244; called by muse, mutect2, varscan2
- ZC3H10 | c.1258T>C p.Y420H | Missense Mutation (SNP) | VAF 60/100 reads (60%) | SIFT deleterious (0); PolyPhen possibly damaging (0.795); catalogued as COSV57769565; called by muse, mutect2, varscan2
- ZC3H15 | c.1073A>G p.Y358C | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.608); catalogued as COSV61923117; called by muse, mutect2, varscan2
- ZFP82 | c.1367G>A p.G456D | Missense Mutation (SNP) | VAF 14/24 reads (58%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.575); catalogued as COSV67566015; called by muse, mutect2, varscan2
- ZKSCAN5 | c.2212A>C p.T738P | Missense Mutation (SNP) | VAF 35/70 reads (50%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.69); catalogued as COSV58743700; called by muse, mutect2, varscan2
- ZNF23 | c.667C>T p.P223S | Missense Mutation (SNP) | VAF 49/85 reads (58%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV61841381; called by muse, mutect2, varscan2
- ZNF329 | c.1515T>A p.H505Q | Missense Mutation (SNP) | VAF 81/192 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV63773033; called by muse, mutect2, varscan2
- ZNF385A | c.619A>G p.K207E (on ENST00000338010 / NM_001130967.3; = p.K187E on NM_015481.3) | Missense Mutation (SNP) | VAF 106/204 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV61493910; called by muse, mutect2, varscan2
- ZNF385D | c.616T>A p.C206S | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55766038; called by muse, mutect2, varscan2
- ZNF462 | c.6020G>T p.R2007L | Missense Mutation (SNP) | VAF 23/103 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV52946422; called by muse, mutect2, varscan2
- ZNF548 | c.856T>C p.C286R | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1568533046, COSV60241516; called by muse, mutect2, varscan2
- ZNF616 | c.1105G>A p.V369I | Missense Mutation (SNP) | VAF 56/125 reads (45%) | SIFT tolerated (0.2); PolyPhen benign (0.017); catalogued as COSV57512310; called by muse, mutect2, varscan2
- ZNF697 | c.869T>A p.L290Q | Missense Mutation (SNP) | VAF 26/49 reads (53%) | SIFT tolerated (0.58); PolyPhen benign (0.014); catalogued as COSV70284233; called by muse, mutect2, varscan2
- ZNF749 | c.1638C>G p.H546Q | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.591); catalogued as COSV61947217; called by muse, mutect2, varscan2
- ABL2 | c.1163_1185del p.Y388Cfs*13 (on ENST00000502732 / NM_007314.4; = p.Y373Cfs*13 on NM_005158.5) | Frame Shift Del (DEL) | VAF 12/94 reads (13%) | called by mutect2, pindel, varscan2
- ASAH2 | c.1316T>G p.L439R | Missense Mutation (SNP) | VAF 60/134 reads (45%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- ATP8B3 | c.3414C>G p.Y1138* | Nonsense Mutation (SNP) | VAF 6/42 reads (14%) | called by muse, mutect2
- CAMTA1 | c.74_78del p.T25Nfs*14 | Frame Shift Del (DEL) | VAF 8/29 reads (28%) | called by mutect2, pindel, varscan2
- CLDN10 | c.147_162del p.W50Pfs*29 | Frame Shift Del (DEL) | VAF 73/250 reads (29%) | called by mutect2, pindel, varscan2
- CPLX3 | c.160_164+27del p.X54_splice | Splice Site (DEL) | VAF 18/44 reads (41%) | called by mutect2, pindel
- DHX34 | c.2431C>T p.Q811* | Nonsense Mutation (SNP) | VAF 40/161 reads (25%) | called by muse, mutect2, varscan2
- ELAPOR1 | c.1274G>A p.W425* | Nonsense Mutation (SNP) | VAF 34/68 reads (50%) | called by muse, mutect2, varscan2
- EZR | c.1412del p.P471Rfs*11 | Frame Shift Del (DEL) | VAF 43/201 reads (21%) | called by mutect2, pindel, varscan2
- HPS3 | c.2897C>G p.S966* | Nonsense Mutation (SNP) | VAF 23/37 reads (62%) | called by muse, mutect2, varscan2
- IFIT2 | c.111del p.V38Yfs*23 | Frame Shift Del (DEL) | VAF 16/35 reads (46%) | called by mutect2, pindel, varscan2
- KCNK15 | c.89A>T p.E30V | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); called by muse, mutect2
- KDM2B | c.1282G>T p.E428* | Nonsense Mutation (SNP) | VAF 15/51 reads (29%) | called by muse, mutect2, varscan2
- KDM6A | c.1531A>T p.R511* | Nonsense Mutation (SNP) | VAF 49/58 reads (84%) | called by muse, mutect2, varscan2
- KMT2A | c.5676T>G p.Y1892* | Nonsense Mutation (SNP) | VAF 15/50 reads (30%) | called by muse, mutect2, varscan2
- LAMA3 | c.6718G>T p.E2240* (on ENST00000313654 / NM_198129.4; = p.E631* on NM_000227.6) | Nonsense Mutation (SNP) | VAF 4/26 reads (15%) | called by muse, mutect2
- MAP3K6 | c.3372_3388del p.E1124Dfs*8 | Frame Shift Del (DEL) | VAF 12/80 reads (15%) | called by mutect2, pindel
- MAP3K7 | c.1215T>G p.Y405* | Nonsense Mutation (SNP) | VAF 10/50 reads (20%) | called by muse, mutect2, varscan2
- MAPK4 | c.1220G>A p.R407H | Missense Mutation (SNP) | VAF 17/27 reads (63%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- MKI67 | c.6862C>T p.Q2288* | Nonsense Mutation (SNP) | VAF 47/69 reads (68%) | called by muse, mutect2, varscan2
- MRC1 | c.4081A>G p.I1361V | Missense Mutation (SNP) | VAF 20/26 reads (77%) | SIFT tolerated (0.37); PolyPhen benign (0.001); called by mutect2, varscan2
- MYO5C | c.2527G>T p.G843* | Nonsense Mutation (SNP) | VAF 110/227 reads (48%) | called by muse, mutect2, varscan2
- NLRP6 | c.2576A>G p.Q859R | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (0.41); PolyPhen benign (0); called by muse, mutect2, varscan2
- NOTCH3 | c.3412_3418del p.I1138Sfs*132 | Frame Shift Del (DEL) | VAF 119/216 reads (55%) | called by mutect2, pindel, varscan2
- PACSIN1 | c.64-8_78del p.X22_splice | Splice Site (DEL) | VAF 12/45 reads (27%) | called by mutect2, pindel, varscan2
- PDE5A | c.1660del p.I556Lfs*35 | Frame Shift Del (DEL) | VAF 10/54 reads (19%) | called by mutect2, pindel, varscan2
- PIGB | c.1001C>T p.A334V | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- PTPN22 | c.2141A>C p.Q714P (on ENST00000359785 / NM_001193431.2; = p.Q659P on NM_012411.5) | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); called by muse, mutect2
- SEPTIN1 | c.1015_1018dup p.C340Sfs*19 (on ENST00000321367; = p.C293Sfs*19 on NM_052838.6 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 55/144 reads (38%) | called by mutect2, pindel, varscan2
- SLC46A2 | c.825del p.A276Qfs*28 | Frame Shift Del (DEL) | VAF 28/114 reads (25%) | called by mutect2, pindel, varscan2
- SMPD2 | c.1201_1213del p.D401Sfs*? | Frame Shift Del (DEL) | VAF 17/80 reads (21%) | called by mutect2, varscan2
- SPTBN5 | c.3272_3294del p.V1091Gfs*2 | Frame Shift Del (DEL) | VAF 10/32 reads (31%) | called by mutect2, pindel
- TRAV13-1 | c.332C>G p.A111G | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.913); called by muse, mutect2, varscan2
- TUBB2B | c.440T>G p.M147R | Missense Mutation (SNP) | VAF 30/159 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- ZMYM1 | c.1044_1054del p.V349Rfs*12 | Frame Shift Del (DEL) | VAF 4/23 reads (17%) | called by mutect2, varscan2
- ZNF827 | c.1087_1093+4del p.X363_splice | Splice Site (DEL) | VAF 4/20 reads (20%) | called by pindel, varscan2
- ZNF827 | c.1081C>G p.P361A | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.099); called by muse, varscan2
- ACP1 | c.268C>T p.L90= | Silent (SNP) | VAF 3/26 reads (12%) | called by muse, mutect2, varscan2
- ADAMTS17 | c.1233C>T p.H411= | Silent (SNP) | VAF 4/36 reads (11%) | called by muse, mutect2
- ADGRG3 | c.1347C>T p.V449= | Silent (SNP) | VAF 22/108 reads (20%) | catalogued as COSV59651758; called by muse, mutect2, varscan2
- AGO1 | c.1191C>A p.I397= | Silent (SNP) | VAF 43/116 reads (37%) | catalogued as rs1328358090, COSV64595884; called by muse, mutect2, varscan2
- AGR2 | c.471A>G p.T157= | Silent (SNP) | VAF 17/79 reads (22%) | catalogued as COSV68597139; called by muse, mutect2, varscan2
- ALS2 | c.2808C>T p.F936= | Silent (SNP) | VAF 6/61 reads (10%) | catalogued as rs778057766, COSV51890094; called by muse, mutect2, varscan2
- AP5B1 | c.732A>T p.A244= | Silent (SNP) | VAF 165/295 reads (56%) | catalogued as COSV57503563; called by muse, mutect2, varscan2
- APC2 | c.1791C>T p.I597= | Silent (SNP) | VAF 47/213 reads (22%) | catalogued as rs142142534; called by muse, mutect2, varscan2
- ARHGEF1 | c.1233C>G p.P411= | Silent (SNP) | VAF 8/27 reads (30%) | catalogued as rs1555848451, COSV61528828; called by muse, mutect2, varscan2
- ARL6IP6 | c.309G>A p.R103= | Silent (SNP) | VAF 32/70 reads (46%) | catalogued as COSV58443543; called by muse, mutect2, varscan2
- ARNT2 | c.1620A>G p.S540= | Silent (SNP) | VAF 28/136 reads (21%) | catalogued as COSV100309312, COSV57588278; called by muse, mutect2, varscan2
- ARRDC1 | c.561C>G p.A187= | Silent (SNP) | VAF 416/849 reads (49%) | catalogued as COSV58378764; called by muse, mutect2, varscan2
- ATPAF1 | c.630T>C p.F210= (on ENST00000574428; = p.F233= on NM_022745.4) | Silent (SNP) | VAF 18/77 reads (23%) | catalogued as rs760317927, COSV61305396; called by muse, mutect2, varscan2
- BCL11B | c.273G>A p.K91= | Silent (SNP) | VAF 150/248 reads (60%) | catalogued as rs750180184, COSV61737528; called by muse, mutect2, varscan2
- BPIFB4 | c.1599A>G p.T533= | Silent (SNP) | VAF 15/54 reads (28%) | catalogued as COSV64951791; called by muse, mutect2, varscan2
- C5AR2 | c.183G>T p.G61= | Silent (SNP) | VAF 91/382 reads (24%) | catalogued as COSV57256818, COSV57257318; called by muse, mutect2, varscan2
- CARS1 | c.1917G>A p.V639= | Silent (SNP) | VAF 35/81 reads (43%) | catalogued as COSV53457552; called by muse, mutect2, varscan2
- CDH2 | c.2637T>G p.G879= | Silent (SNP) | VAF 16/91 reads (18%) | catalogued as COSV52288918; called by muse, mutect2, varscan2
- CHD6 | c.5670A>T p.V1890= | Silent (SNP) | VAF 26/50 reads (52%) | catalogued as COSV64692898, COSV64694628; called by muse, mutect2, varscan2
- CHST4 | c.774G>A p.K258= | Silent (SNP) | VAF 11/84 reads (13%) | catalogued as COSV58297808; called by muse, mutect2, varscan2
- CIT | c.489C>A p.A163= | Silent (SNP) | VAF 76/175 reads (43%) | catalogued as COSV55876427; called by muse, mutect2, varscan2
- COL6A6 | c.6435C>G p.G2145= | Silent (SNP) | VAF 27/169 reads (16%) | catalogued as COSV62031702; called by muse, mutect2, varscan2
- CRYBG1 | c.6186T>G p.S2062= | Silent (SNP) | VAF 41/81 reads (51%) | catalogued as COSV64813470; called by muse, mutect2, varscan2
- CSMD3 | c.468C>G p.T156= | Silent (SNP) | VAF 15/68 reads (22%) | catalogued as COSV52252278, COSV99831319; called by muse, mutect2, varscan2
- CYB5R1 | c.87G>A p.L29= | Silent (SNP) | VAF 10/52 reads (19%) | called by muse, mutect2
- DCHS1 | c.3870A>T p.T1290= | Silent (SNP) | VAF 16/41 reads (39%) | catalogued as COSV55039408; called by muse, mutect2, varscan2
- DHH | c.99C>T p.R33= | Silent (SNP) | VAF 13/43 reads (30%) | catalogued as rs751018684, COSV57202541; called by muse, mutect2, varscan2
- EDEM1 | c.480C>T p.C160= | Silent (SNP) | VAF 20/60 reads (33%) | catalogued as COSV56583354; called by muse, mutect2, varscan2
- EDEM2 | c.9C>T p.F3= | Silent (SNP) | VAF 61/105 reads (58%) | catalogued as COSV65712593; called by muse, mutect2, varscan2
- EFNB2 | c.747G>A p.L249= | Silent (SNP) | VAF 69/190 reads (36%) | catalogued as COSV55366398; called by muse, mutect2, varscan2
- EIF2AK1 | c.531A>G p.G177= | Silent (SNP) | VAF 42/63 reads (67%) | catalogued as COSV52241435; called by muse, mutect2, varscan2
- FANCB | c.1557G>T p.R519= | Silent (SNP) | VAF 21/29 reads (72%) | catalogued as COSV60761012; called by muse, mutect2, varscan2
- FBXL5 | c.1737T>G p.P579= | Silent (SNP) | VAF 9/22 reads (41%) | catalogued as COSV58012765; called by muse, mutect2, varscan2
- FICD | c.1005A>G p.V335= | Silent (SNP) | VAF 49/90 reads (54%) | catalogued as COSV57209306; called by muse, mutect2, varscan2
- FLVCR1 | c.648C>T p.F216= | Silent (SNP) | VAF 48/119 reads (40%) | catalogued as COSV63134214; called by muse, mutect2, varscan2
- FPR3 | c.696C>T p.H232= | Silent (SNP) | VAF 6/12 reads (50%) | called by mutect2, varscan2
- FUZ | c.291A>G p.R97= | Silent (SNP) | VAF 9/28 reads (32%) | catalogued as COSV58242317; called by muse, mutect2, varscan2
- FZD7 | c.174G>C p.T58= | Silent (SNP) | VAF 73/300 reads (24%) | catalogued as rs556542493, COSV53810828; called by muse, mutect2, varscan2
- H2AC11 | c.378G>A p.K126= | Silent (SNP) | VAF 37/109 reads (34%) | catalogued as COSV60362403; called by muse, mutect2, varscan2
- HEATR4 | c.2463C>A p.I821= | Silent (SNP) | VAF 36/61 reads (59%) | catalogued as rs747162876, COSV58374391; called by muse, mutect2, varscan2
- HIPK1 | c.2874G>A p.L958= | Silent (SNP) | VAF 54/171 reads (32%) | catalogued as COSV61249442; called by muse, mutect2, varscan2
- HLA-C | c.390C>T p.D130= | Silent (SNP) | VAF 78/489 reads (16%) | catalogued as rs45558335, COSV66115691; called by muse, mutect2
- HNRNPUL1 | c.1812C>T p.P604= | Silent (SNP) | VAF 19/84 reads (23%) | catalogued as COSV54564957; called by muse, mutect2, varscan2
- HSP90AA1 | c.60G>A p.R20= | Silent (SNP) | VAF 26/41 reads (63%) | called by muse, mutect2, varscan2
- HTR2A | c.915C>T p.S305= | Silent (SNP) | VAF 6/11 reads (55%) | catalogued as rs766775131, COSV66327889; called by muse, mutect2, varscan2
- IBTK | c.630A>C p.G210= | Silent (SNP) | VAF 31/93 reads (33%) | catalogued as COSV60394787; called by muse, mutect2, varscan2
- IL32 | c.601C>T p.L201= (on ENST00000396890 / NM_001308078.4; = p.L155= on NM_004221.7 and 1 other RefSeq transcript) | Silent (SNP) | VAF 10/76 reads (13%) | catalogued as rs763056959, COSV50404490; called by muse, mutect2, varscan2
- ITGAV | c.2559T>C p.T853= | Silent (SNP) | VAF 24/60 reads (40%) | catalogued as COSV53716172; called by muse, mutect2, varscan2
- ITIH5 | c.1188G>T p.R396= | Silent (SNP) | VAF 45/86 reads (52%) | catalogued as COSV53670549; called by muse, mutect2, varscan2
- ITPR3 | c.231T>C p.T77= | Silent (SNP) | VAF 59/140 reads (42%) | catalogued as COSV65412568; called by muse, mutect2, varscan2
- JRK | c.1548G>A p.R516= | Silent (SNP) | VAF 19/54 reads (35%) | called by muse, mutect2, varscan2
- JUP | c.738C>T p.A246= | Silent (SNP) | VAF 25/130 reads (19%) | catalogued as COSV60279068; called by muse, mutect2, varscan2
- KATNB1 | c.846T>C p.N282= | Silent (SNP) | VAF 29/98 reads (30%) | catalogued as rs1555583948, COSV65561341; called by muse, mutect2, varscan2
- KCND2 | c.1329T>C p.A443= | Silent (SNP) | VAF 18/49 reads (37%) | catalogued as rs1161024740, COSV58593181; called by muse, mutect2, varscan2
- LLGL2 | c.2568C>T p.A856= | Silent (SNP) | VAF 74/179 reads (41%) | catalogued as rs758645564, COSV51375790; called by muse, mutect2, varscan2
- LOXL3 | c.1530C>G p.T510= | Silent (SNP) | VAF 43/86 reads (50%) | catalogued as COSV51210197; called by muse, mutect2, varscan2
- LRP1 | c.11025C>T p.G3675= | Silent (SNP) | VAF 35/155 reads (23%) | catalogued as rs766130397, COSV54509595; called by muse, mutect2, varscan2
- LRP5 | c.4407G>T p.G1469= | Silent (SNP) | VAF 35/72 reads (49%) | catalogued as rs763815058, COSV53719967; called by muse, mutect2, varscan2
- LRRC47 | c.1629C>T p.D543= | Silent (SNP) | VAF 50/170 reads (29%) | catalogued as rs774557849, COSV65563177; called by muse, mutect2, varscan2
- LRRN2 | c.1239C>T p.F413= | Silent (SNP) | VAF 21/94 reads (22%) | catalogued as COSV65784339; called by muse, mutect2, varscan2
- MDN1 | c.7398C>T p.N2466= | Silent (SNP) | VAF 53/120 reads (44%) | catalogued as rs1276689892, COSV65525891; called by muse, mutect2, varscan2
- MFSD11 | c.243C>G p.A81= | Silent (SNP) | VAF 28/77 reads (36%) | catalogued as COSV60626270; called by muse, mutect2, varscan2
- MUC20 | c.1743C>G p.L581= | Silent (SNP) | VAF 15/140 reads (11%) | catalogued as rs1458545713, COSV57852581; called by muse, mutect2, varscan2
- MYO1E | c.294C>T p.N98= | Silent (SNP) | VAF 11/43 reads (26%) | catalogued as COSV55691514; called by muse, mutect2, varscan2
- NCKAP5 | c.3432T>C p.T1144= | Silent (SNP) | VAF 15/71 reads (21%) | catalogued as COSV58461420; called by muse, mutect2, varscan2
- NDRG4 | c.180C>T p.T60= (on ENST00000570248 / NM_001378344.1; = p.T92= on NM_020465.4 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 42/244 reads (17%) | catalogued as COSV50749575; called by muse, mutect2, varscan2
- NECAP1 | c.474C>G p.T158= | Silent (SNP) | VAF 12/26 reads (46%) | catalogued as COSV60250040; called by muse, mutect2, varscan2
- NELL2 | c.1995T>C p.C665= | Silent (SNP) | VAF 38/113 reads (34%) | catalogued as rs1329008621, COSV61580711; called by muse, mutect2, varscan2
- NRBF2 | c.132C>G p.A44= | Silent (SNP) | VAF 10/61 reads (16%) | catalogued as COSV53259914; called by muse, mutect2, varscan2
- NRXN2 | c.192G>T p.A64= | Silent (SNP) | VAF 19/26 reads (73%) | called by muse, mutect2
- PAH | c.741C>T p.G247= | Silent (SNP) | VAF 16/39 reads (41%) | catalogued as rs1355030586, COSV61018806; called by muse, mutect2, varscan2
- PCDHB6 | c.1773C>T p.D591= | Silent (SNP) | VAF 38/207 reads (18%) | catalogued as COSV99169956; called by muse, mutect2, varscan2
- PFKP | c.1546C>T p.L516= | Silent (SNP) | VAF 82/287 reads (29%) | catalogued as COSV66900001; called by muse, mutect2, varscan2
- PHLPP2 | c.1509G>T p.L503= | Silent (SNP) | VAF 16/49 reads (33%) | catalogued as COSV62426086; called by muse, mutect2, varscan2
- PLCE1 | c.4191C>T p.P1397= | Silent (SNP) | VAF 21/25 reads (84%) | catalogued as COSV53361851; called by muse, mutect2, varscan2
- PLEKHG3 | c.1206C>G p.L402= (on ENST00000394691; = p.L458= on NM_001308147.2) | Silent (SNP) | VAF 34/137 reads (25%) | catalogued as COSV55981799; called by muse, mutect2, varscan2
- POLH | c.837C>T p.T279= | Silent (SNP) | VAF 19/45 reads (42%) | catalogued as COSV64780147; called by muse, mutect2, varscan2
- PRDX5 | c.27G>A p.L9= | Silent (SNP) | VAF 31/155 reads (20%) | catalogued as COSV50007051, COSV99135042; called by muse, mutect2, varscan2
- PRG4 | c.3732G>A p.V1244= | Silent (SNP) | VAF 7/26 reads (27%) | catalogued as rs780627785, COSV63356056; called by muse, mutect2, varscan2
- PRPF18 | c.627T>C p.Y209= | Silent (SNP) | VAF 11/56 reads (20%) | catalogued as COSV60725887; called by muse, mutect2, varscan2
- RAB3B | c.99T>G p.V33= | Silent (SNP) | VAF 81/125 reads (65%) | catalogued as COSV63228399; called by muse, mutect2, varscan2
- RALGAPA1 | c.66G>A p.K22= | Silent (SNP) | VAF 35/66 reads (53%) | catalogued as rs751357424, COSV51890244; called by muse, mutect2, varscan2
- RASIP1 | c.1089C>T p.P363= | Silent (SNP) | VAF 21/90 reads (23%) | catalogued as COSV55806803; called by muse, mutect2, varscan2
- RBBP8 | c.2283A>G p.L761= | Silent (SNP) | VAF 8/26 reads (31%) | called by muse, mutect2, varscan2
- RPRD2 | c.2772G>T p.G924= | Silent (SNP) | VAF 148/281 reads (53%) | catalogued as COSV64819770, COSV64822095; called by muse, mutect2, varscan2
- SCAP | c.69A>G p.A23= | Silent (SNP) | VAF 6/27 reads (22%) | catalogued as COSV55563905; called by muse, mutect2, varscan2
- SCFD2 | c.108G>T p.L36= | Silent (SNP) | VAF 80/162 reads (49%) | catalogued as COSV66375066; called by muse, mutect2, varscan2
- SEL1L2 | c.1074C>G p.A358= | Silent (SNP) | VAF 28/145 reads (19%) | catalogued as COSV53155217; called by muse, mutect2, varscan2
- SERINC1 | c.414T>C p.I138= | Silent (SNP) | VAF 7/14 reads (50%) | catalogued as COSV60102515; called by muse, mutect2, varscan2
- SLC1A4 | c.1524C>T p.P508= | Silent (SNP) | VAF 23/154 reads (15%) | catalogued as COSV52235400; called by muse, mutect2, varscan2
- SLC30A7 | c.153G>A p.V51= | Silent (SNP) | VAF 8/28 reads (29%) | catalogued as rs1355608941, COSV63018188; called by muse, mutect2, varscan2
- STK38 | c.627C>T p.I209= | Silent (SNP) | VAF 38/78 reads (49%) | catalogued as COSV57709931; called by muse, mutect2, varscan2
- SUPT16H | c.987C>A p.V329= | Silent (SNP) | VAF 15/122 reads (12%) | catalogued as COSV53523869; called by muse, mutect2, varscan2
- SYT2 | c.879G>A p.E293= | Silent (SNP) | VAF 67/129 reads (52%) | catalogued as COSV66142567; called by muse, mutect2, varscan2
- TAF4 | c.2013C>T p.S671= | Silent (SNP) | VAF 132/252 reads (52%) | catalogued as rs370500200; called by muse, mutect2, varscan2
- TNC | c.2034C>A p.I678= | Silent (SNP) | VAF 16/64 reads (25%) | catalogued as COSV60787783; called by muse, mutect2, varscan2
- TTN | c.48183T>G p.P16061= (on ENST00000591111; = p.P8637= on NM_003319.4) | Silent (SNP) | VAF 52/208 reads (25%) | catalogued as COSV60207142; called by muse, mutect2, varscan2
- USP15 | c.2226G>A p.R742= (on ENST00000280377 / NM_001351159.2; = p.R713= on NM_006313.3 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 22/34 reads (65%) | catalogued as COSV54795777; called by muse, mutect2, varscan2
- WIF1 | c.204T>C p.H68= | Silent (SNP) | VAF 24/50 reads (48%) | catalogued as COSV54133838; called by muse, mutect2, varscan2
- WNK1 | c.4194C>T p.L1398= (on ENST00000315939 / NM_018979.4; = p.L1151= on NM_014823.3) | Silent (SNP) | VAF 37/77 reads (48%) | catalogued as COSV60040031; called by muse, mutect2, varscan2
- ZFYVE26 | c.5931C>T p.D1977= | Silent (SNP) | VAF 51/188 reads (27%) | catalogued as COSV61331398; called by muse, mutect2, varscan2
- ZNF136 | c.1434T>C p.C478= | Silent (SNP) | VAF 11/21 reads (52%) | catalogued as COSV59711320; called by muse, mutect2, varscan2
- ZNF485 | c.1065G>A p.Q355= | Silent (SNP) | VAF 19/97 reads (20%) | catalogued as COSV62424937; called by muse, mutect2, varscan2
- ZNF827 | c.1080A>G p.K360= | Silent (SNP) | VAF 4/22 reads (18%) | catalogued as COSV101061414; called by muse, varscan2
- ZZZ3 | c.1512G>A p.Q504= | Silent (SNP) | VAF 8/26 reads (31%) | catalogued as COSV66234340; called by muse, mutect2, varscan2
- ARMC6 | c.*53G>T | 3'UTR (SNP) | VAF 7/27 reads (26%) | catalogued as COSV99522950; called by muse, mutect2
- CUX1 | chr7:101816029 A>C | 5'Flank (SNP) | VAF 51/144 reads (35%) | catalogued as COSV99470725; called by muse, mutect2, varscan2
- FMN1 | c.2044-2791C>T | Intron (SNP) | VAF 10/45 reads (22%) | catalogued as COSV57928494; called by muse, mutect2, varscan2
- MACF1 | c.15832-11199C>G | Intron (SNP) | VAF 8/24 reads (33%) | catalogued as COSV57133169; called by muse, mutect2, varscan2
- MARCHF1 | c.-322-85376G>T | Intron (SNP) | VAF 8/16 reads (50%) | catalogued as COSV101551420; called by muse, mutect2, varscan2
- MARCHF1 | c.-322-85377G>C | Intron (SNP) | VAF 9/17 reads (53%) | called by muse, mutect2, varscan2
- PRKACB | c.47-34797_47-34793dup | Intron (INS) | VAF 13/63 reads (21%) | called by mutect2, pindel, varscan2
- PTPRK | c.100+28449C>T | Intron (SNP) | VAF 10/26 reads (38%) | called by muse, mutect2, varscan2
- RBFOX1 | c.996-15731G>A | Intron (SNP) | VAF 14/76 reads (18%) | catalogued as rs900149341, COSV60967333, COSV60976172; called by muse, mutect2, varscan2
- UROC1 | c.903-668G>C | Intron (SNP) | VAF 4/80 reads (5%) | called by muse, mutect2
